Somatic mutation profile of tumor specimen HCM-BROD-0783-C71-02A (aliquot HCM-BROD-0783-C71-02A-01D-A87L-36) from HCMI case HCM-BROD-0783-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.9 years (19,673 days).
Specimen HCM-BROD-0783-C71-02A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db98c1f5-0148-4813-9df7-b88add965db3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0783-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0783-C71-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52db2b13-91f0-4f33-9de2-a57d039c9db3

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2513C>A p.S838* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as rs1131690908, CM952423, COSV57298758, COSV57309724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 123/187 reads (66%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, varscan2
- AHNAK2 | c.12067G>A p.A4023T | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as rs200136053, COSV100317552; called by muse, mutect2, varscan2
- CDCP1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1345319029; called by muse, mutect2
- CIT | c.3241C>T p.R1081W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs765007099; called by muse, mutect2, varscan2
- CNTNAP2 | c.1668C>G p.D556E | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1446141045; called by muse, mutect2, varscan2
- DCHS1 | c.9133C>T p.R3045C | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775574359; called by muse, mutect2, varscan2
- DEGS2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 235/575 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs776729713, COSV99979255; called by muse, mutect2, varscan2
- DNAH12 | c.6361C>T p.R2121C (on ENST00000351747; = p.R2140C on NM_001366028.2) | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782415526; called by muse, mutect2, varscan2
- DNAH17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747233018, COSV67750093; called by muse, mutect2, varscan2
- DOCK5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs765575956; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 151/437 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs373451243; called by muse, mutect2, varscan2
- GPR4 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59917386; called by muse, mutect2, varscan2
- HEPH | c.898G>T p.E300* (on ENST00000343002; = p.E33* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 133/346 reads (38%) | catalogued as COSV57959361; called by muse, mutect2, varscan2
- KCNA4 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs376821611; called by muse, mutect2, varscan2
- KIFC2 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 121/305 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs778514593; called by muse, mutect2, varscan2
- MTA2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99604528; called by muse, mutect2, varscan2
- OR11H7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1051026051; called by muse, varscan2
- PIK3CG | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs758375337, COSV63249028; called by muse, mutect2, varscan2
- PKHD1 | c.10445G>A p.R3482H | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs143915416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs140793596; called by muse, mutect2, varscan2
- SLCO6A1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1407396276, COSV65806754, COSV65815279; called by muse, mutect2, varscan2
- STKLD1 | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs1326949403; called by muse, mutect2, varscan2
- TLR8 | c.1415G>A p.R472H (on ENST00000218032 / NM_138636.5; = p.R490H on NM_016610.4) | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs910600091, COSV54317482; called by muse, mutect2, varscan2
- UBR4 | c.10142G>A p.G3381D | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.199); catalogued as rs766755783; called by muse, mutect2, varscan2
- EMILIN2 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.88); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- G3BP1 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 58/209 reads (28%) | called by muse, mutect2, varscan2
- MAP2K7 | c.509T>G p.V170G | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NOS1 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDA3 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 173/500 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPIP5K2 | c.3442G>C p.A1148P (on ENST00000358359 / NM_001276277.3; = p.A1127P on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.184); called by muse, mutect2
- PPP4R3C | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SLC2A9 | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLCO6A1 | c.1079T>A p.L360H | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- SPIN2A | c.563del p.I188Tfs*19 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- TJP1 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIB2 | c.801del p.R268Vfs*30 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | called by mutect2, varscan2
- ZFP42 | c.288A>T p.E96D | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BLM | c.1875T>C p.N625= | Silent (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- CLSTN2 | c.1389T>C p.F463= | Silent (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.510G>A p.A170= | Silent (SNP) | VAF 95/258 reads (37%) | catalogued as rs1252903107, COSV70552580; called by muse, mutect2, varscan2
- HLCS | c.627G>A p.P209= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as rs73196003, COSV60797702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR3 | c.2463G>A p.A821= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs202110116, COSV65413613; called by muse, mutect2, varscan2
- MLPH | c.1281G>A p.A427= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs202229121, COSV52820316; called by muse, mutect2
- OR5M3 | c.855C>A p.P285= | Silent (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- OVOL2 | c.348G>A p.S116= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as rs769786984, COSV99602539, COSV99602588; called by muse, mutect2, varscan2
- PASK | c.783C>T p.H261= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as rs771988343; called by muse, mutect2
- PRKG2 | c.1935G>A p.T645= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV52332557; called by muse, mutect2, varscan2
- TBC1D12 | c.720C>T p.A240= | Silent (SNP) | VAF 148/258 reads (57%) | catalogued as rs1216840557; called by muse, mutect2, varscan2
- TRIM71 | c.135C>T p.G45= | Silent (SNP) | VAF 162/421 reads (38%) | catalogued as rs772452554; called by muse, mutect2, varscan2
- VSX1 | c.612C>T p.P204= | Silent (SNP) | VAF 91/239 reads (38%) | catalogued as rs200369946; called by muse, mutect2, varscan2
- CDKL2 | c.1416+4372C>T | Intron (SNP) | VAF 66/229 reads (29%) | catalogued as rs779941729; called by muse, mutect2, varscan2
- CREBZF | c.*260A>G | 3'UTR (SNP) | VAF 125/327 reads (38%) | called by muse, mutect2, varscan2
- ZNF624 | chr17:16617199 C>T | 3'Flank (SNP) | VAF 87/257 reads (34%) | called by muse, mutect2, varscan2
